Somatic mutation profile of tumor specimen TCGA-BL-A13I-01A (aliquot TCGA-BL-A13I-01A-11D-A271-08) from TCGA case TCGA-BL-A13I, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 57.2 years (20,885 days).
Specimen TCGA-BL-A13I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a0d26ae-82b5-4f15-bc56-350d6424219a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A13I-10A (Blood Derived Normal), aliquot TCGA-BL-A13I-10A-01D-A271-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcd46a07-1ea9-4c3c-bb84-0fecd44c6e4f

The open-access MAF lists 111 somatic variants for this specimen: 90 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 20, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.5050A>C p.S1684R | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101315678; called by muse, mutect2
- AP002748.5 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 34/185 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757307889, COSV59149588; called by muse, mutect2, varscan2
- ARID1B | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 18/123 reads (15%) | catalogued as rs1554234415, COSV99268166; called by muse, mutect2, varscan2
- ATP10A | c.1505A>T p.H502L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as COSV100791013; called by muse, mutect2, varscan2
- ATP5PO | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51708572; called by muse, mutect2, varscan2
- BAG4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV54860069; called by muse, mutect2, varscan2
- BNC2 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV101032590; called by muse, mutect2, varscan2
- C8orf34 | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs867335537, COSV57400749, COSV57402183; called by muse, mutect2
- CAMKK2 | c.797-1G>A p.X266_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | catalogued as COSV61215366; called by muse, mutect2, varscan2
- CATSPER2 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs763965666, COSV58661086; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2, varscan2
- CDH16 | c.2149C>T p.R717C | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs140255974; called by muse, mutect2, varscan2
- CFAP70 | c.2248C>G p.Q750E | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV60282023, COSV60283998; called by muse, mutect2, varscan2
- CHD7 | c.7369A>T p.N2457Y | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.094); catalogued as COSV71111909; called by muse, mutect2, varscan2
- CIAPIN1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200237459, COSV67953414; called by muse, mutect2, varscan2
- COMMD6 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63322558; called by muse, mutect2, varscan2
- CTNND2 | c.172C>A p.Q58K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV58896469; called by muse, mutect2, varscan2
- CYP2C9 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs150435881, COSV53246052; called by muse, mutect2, varscan2
- CYP2U1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60549066; called by muse, mutect2, varscan2
- DDX3X | c.1058A>T p.D353V (on ENST00000399959; = p.D354V on NM_001356.5) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863257, COSV67863269; called by muse, mutect2, varscan2
- DHX32 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771021543, COSV52940914; called by muse, mutect2, varscan2
- DISP1 | c.3921G>C p.Q1307H | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV52657899, COSV52660492; called by muse, mutect2, varscan2
- FAM186B | c.344T>C p.I115T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as rs771352682, COSV57721893; called by muse, mutect2, varscan2
- FAT1 | c.6828C>G p.I2276M | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV71674673; called by muse, mutect2, varscan2
- FOS | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771351750, COSV57839117; called by muse, mutect2, varscan2
- FREM2 | c.4723G>A p.V1575M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV54841008; called by muse, mutect2, varscan2
- GABRA1 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1164973274, COSV50099709, COSV50102525; called by muse, mutect2, varscan2
- GHSR | c.36C>G p.F12L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV53840039; called by muse, mutect2
- HERC1 | c.7057G>C p.E2353Q | Missense Mutation (SNP) | VAF 37/200 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.616); catalogued as COSV71247063, COSV71248400; called by muse, mutect2, varscan2
- IDE | c.817A>C p.K273Q | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV56424347; called by muse, mutect2, varscan2
- IL16 | c.3020C>G p.S1007C (on ENST00000302987 / NM_172217.5; = p.S306C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV57264590; called by muse, mutect2, varscan2
- KMT2C | c.1483G>C p.E495Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.782); catalogued as COSV51451790; called by muse, mutect2
- LAMA3 | c.7274C>G p.S2425* (on ENST00000313654 / NM_198129.4; = p.S816* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV52541290; called by muse, mutect2, varscan2
- LAMA5 | c.7384G>C p.D2462H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99438853; called by muse, mutect2
- LTBP1 | c.2784G>C p.Q928H (on ENST00000404816 / NM_206943.4; = p.Q602H on NM_000627.4) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV63189789; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.95); catalogued as COSV100824942, COSV64055959; called by muse, mutect2
- MRGPRX2 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV61674328; called by muse, mutect2, varscan2
- MS4A8 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as rs148191741; called by muse, mutect2, varscan2
- MTHFR | c.1525C>T p.Q509* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100453521; called by muse, mutect2, varscan2
- MYH4 | c.871C>G p.Q291E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55115570, COSV55120002; called by muse, mutect2, varscan2
- NBPF1 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 103/672 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.917); catalogued as rs758682530, COSV99844283; called by muse, mutect2, varscan2
- NCAM1 | c.2510C>A p.A837E (on ENST00000316851 / NM_181351.5; = p.A827E on NM_000615.7) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV100377262; called by muse, mutect2, varscan2
- NINL | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV99625006; called by muse, mutect2, varscan2
- NRBP1 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV51994616; called by muse, mutect2, varscan2
- NRG3 | c.2080C>A p.L694M (on ENST00000404547 / NM_001370084.1; = p.L670M on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.05); catalogued as rs1044487187, COSV64551529, COSV64567739; called by muse, mutect2, varscan2
- NUFIP2 | c.1477C>G p.Q493E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV56603934; called by muse, mutect2, varscan2
- NUP214 | c.2142G>C p.Q714H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845224, COSV63910409; called by muse, mutect2, varscan2
- OPCML | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as COSV59429349; called by muse, mutect2, varscan2
- OR5I1 | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.373); catalogued as COSV100041302; called by muse, mutect2
- OSCP1 | c.205C>G p.Q69E (on ENST00000356637 / NM_001330493.1; = p.Q59E on NM_145047.5) | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV52486639; called by muse, mutect2, varscan2
- PCDH17 | c.2208G>C p.E736D | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as COSV64975208; called by muse, mutect2, varscan2
- PCDHAC1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs1554203825, COSV99165402; called by muse, mutect2
- PCDHB6 | c.1873G>T p.A625S | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV50701759, COSV50709609; called by muse, mutect2, varscan2
- PCLO | c.13493A>T p.K4498I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100429613; called by muse, mutect2
- PIP4K2C | c.554T>A p.F185Y | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.169); catalogued as COSV61606429; called by muse, mutect2, varscan2
- PMM1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV53448066; called by muse, varscan2
- PXDN | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.718); catalogued as COSV53237161; called by muse, mutect2
- RAB11FIP1 | c.1790C>G p.S597C | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV54760992; called by muse, mutect2, varscan2
- RBAK | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62331699; called by muse, mutect2, varscan2
- RIMKLB | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV100223820; called by muse, mutect2, varscan2
- RNGTT | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763371848, COSV55646778; called by muse, mutect2, varscan2
- SHPRH | c.553A>G p.M185V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1302967406, COSV51611657; called by muse, mutect2, varscan2
- SLC35B2 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773882742, COSV51489997; called by muse, mutect2, varscan2
- SLCO4C1 | c.1469+1G>A p.X490_splice | Splice Site (SNP) | VAF 4/27 reads (15%) | catalogued as COSV60516776; called by muse, mutect2
- SPATA31A1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV66533618; called by muse, mutect2, varscan2
- SRPRB | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs951540380, COSV72048441; called by muse, mutect2, varscan2
- SSB | c.704A>C p.K235T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV53626871; called by muse, mutect2, varscan2
- SV2C | c.1503-1G>T p.X501_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as COSV59221928; called by muse, mutect2, varscan2
- TFE3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV100252443; called by muse, mutect2, varscan2
- TLCD3A | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56746222; called by muse, mutect2, varscan2
- TNC | c.4775G>A p.G1592D | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); catalogued as COSV60785954; called by muse, mutect2, varscan2
- TTC25 | c.492G>A p.M164I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782641073, COSV66368362; called by muse, mutect2
- VCX3B | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.178); catalogued as COSV66842875; called by muse, mutect2, varscan2
- VDAC2 | c.536A>C p.N179T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100040867; called by muse, mutect2, varscan2
- WDR49 | c.1057G>C p.D353H (on ENST00000308378 / NM_001366158.1; = p.D694H on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.275); catalogued as COSV100392062, COSV57709026; called by muse, mutect2
- XIRP2 | c.8180A>G p.K2727R (on ENST00000628543; = p.K2902R on NM_152381.6) | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV54708266; called by muse, mutect2, varscan2
- YIPF6 | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV65855889; called by muse, mutect2, varscan2
- ZBTB32 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV52890950; called by muse, mutect2
- ZC3H12B | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs754052721, COSV59047272, COSV59047535; called by muse, mutect2, varscan2
- ZNF613 | c.1681G>T p.D561Y (on ENST00000293471 / NM_001031721.4; = p.D525Y on NM_024840.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99522871; called by muse, mutect2, varscan2
- ARID1A | c.3118_3119del p.N1040Sfs*6 | Frame Shift Del (DEL) | VAF 27/103 reads (26%) | called by mutect2, pindel, varscan2
- GABRG1 | c.154del p.T52Pfs*17 | Frame Shift Del (DEL) | VAF 19/97 reads (20%) | called by mutect2, pindel, varscan2
- IGKV3-20 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RNF125 | c.61dup p.A21Gfs*22 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by pindel, varscan2
- RUNX2 | c.1103del p.G368Afs*116 (on ENST00000371438; = p.G346Afs*116 on NM_001015051.3) | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- SYNRG | c.2498C>G p.S833C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPTE | c.562C>T p.P188S (on ENST00000618007 / NM_199261.4; = p.P170S on NM_199259.4) | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2
- TSC22D2 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- AFF3 | c.3666C>T p.S1222= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1354777142, COSV57857397; called by muse, mutect2, varscan2
- BIRC6 | c.6321A>G p.E2107= | Silent (SNP) | VAF 26/167 reads (16%) | catalogued as COSV70200856; called by muse, mutect2, varscan2
- C10orf90 | c.594C>T p.F198= | Silent (SNP) | VAF 10/94 reads (11%) | catalogued as COSV52957174; called by muse, mutect2, varscan2
- CCR5 | c.249C>T p.V83= | Silent (SNP) | VAF 13/142 reads (9%) | catalogued as COSV52751921; called by muse, mutect2
- CD209 | c.387G>T p.R129= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV52654768, COSV52654986; called by muse, varscan2
- CFAP65 | c.3399G>A p.L1133= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV58562234; called by muse, mutect2, varscan2
- CUL9 | c.5172C>T p.F1724= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as rs781114971, COSV52728616, COSV52729983; called by muse, mutect2, varscan2
- DNAH10 | c.13099C>A p.R4367= (on ENST00000409039; = p.R4306= on NM_207437.3) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV53018474, COSV53020168; called by muse, mutect2, varscan2
- ENPP3 | c.504A>G p.G168= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV62954673; called by muse, mutect2, varscan2
- FERD3L | c.138C>T p.L46= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs267601446, COSV99284795; called by muse, mutect2, varscan2
- GPR152 | c.618C>G p.L206= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV56886861; called by muse, mutect2, varscan2
- KLHL36 | c.48C>T p.I16= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV50719772; called by muse, mutect2, varscan2
- OPCML | c.174C>A p.T58= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59429336; called by muse, mutect2, varscan2
- P3H4 | c.573C>T p.V191= | Silent (SNP) | VAF 37/276 reads (13%) | catalogued as COSV58636139; called by muse, mutect2, varscan2
- RTL8C | c.330C>T p.D110= | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as COSV57060190; called by mutect2, varscan2
- SIGLEC8 | c.1002G>A p.Q334= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1436601241, COSV100367199; called by muse, mutect2, varscan2
- SLC5A11 | c.1641C>T p.S547= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV61742078; called by muse, mutect2, varscan2
- SPEG | c.4071C>T p.F1357= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV56671274; called by muse, mutect2, varscan2
- ZNF318 | c.5871T>A p.A1957= | Silent (SNP) | VAF 12/91 reads (13%) | catalogued as COSV58933517; called by muse, mutect2, varscan2
- ZNF765 | c.1425C>T p.F475= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV67182743; called by muse, varscan2
- C3P1 | n.3326A>G | RNA (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
